TARGET case TARGET-40-NAAGJU — Osteosarcoma (TARGET-OS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Osseous and Chondromatous Neoplasms; Primary site: Bones, joints and articular cartilage of limbs. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/76bace42-4c05-5c20-b441-f6b1fee2c300

Demographics
Sex at birth: male; Race: asian; Age at index: 12 years; Vital status: Dead; Days to death: 368 days (1.0 years).

Diagnoses (1)
1. Osteosarcoma, NOS: ICD-O-3 morphology code: 9180/3; ICD-10 code: C40.2; Tissue or organ of origin: Long bones of lower limb and associated joints; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 12.8 years (4,671 days); Year of diagnosis: 2006; Metastasis at diagnosis: No Metastasis; Days to last follow up: 368 days (1.0 years).
   Pathology details: Necrosis percent: 90.

Follow-up (2 entries)
- Days to follow up: 275 days; Progression or recurrence: Yes; Progression or recurrence anatomic site: Lung, NOS; Days to progression: 275 days; Days to first event: 275 days; First event: Relapse.
- Days to follow up: 368 days (1.0 years); Year of follow up: 2007.

Biospecimens (3 samples)
- Sample TARGET-40-NAAGJU-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
- Sample TARGET-40-NAAGJU-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.
- Sample TARGET-40-NAAGJU-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue.

Additional fields from the TARGET clinical supplement workbook TARGET_OS_ClinicalData_Discovery_and_Validation_Percent_Tumor_Supplement_20230329.xlsx (sheet OS Data), for sample TARGET-40-NAAGJU-01A-01D:
- Specimen Type: tumor DNA
- Diagnosis Confirmed: yes/yes
- % Tumor Nuclei: Top from Biopsy: 90/50
- % Non Tumor Nuclei: Top from Biopsy: 10/50
- % Cellular Tumor: Top from Biopsy: 40/10
- % Normal: Top from Biopsy: 50/90
- % Stroma: Top from Biopsy: 0/0
- % Necrosis: Top from Biopsy: 10/0

Additional fields from the TARGET clinical supplement workbook TARGET_OS_ClinicalData_Validation_20230329.xlsx (sheet Clinical Data):
- Overall Survival Time in Days: 368
- Protocol: Other osteosarcoma
- Disease at diagnosis: Non-metastatic (confirmed)
- Primary tumor site: Leg/foot
- Specific tumor site: Femur
- Specific tumor region: Distal
- Definitive Surgery: Amputation
- Primary site progression: No
- Site of initial relapse: Lung
- Time to first enrollment on relapse protocol in days: 283
